Somatic mutation profile of tumor specimen MP2PRT-PATGYA-TMP1-A (aliquot MP2PRT-PATGYA-TMP1-A-1-0-D-A81O-36) from MP2PRT case MP2PRT-PATGYA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.5 years (1,649 days).
Specimen MP2PRT-PATGYA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 094e6064-1646-4c69-8072-eaf2ae671c45.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATGYA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATGYA-NB1-A-1-0-D-A81O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8c1e46ef-54a4-4a74-ab3c-65ee46ddc1ef

The open-access MAF lists 34 somatic variants for this specimen: 24 protein-altering or splice-affecting, 7 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 7, Intron 1, 3'UTR 1, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL4A3 | c.3499G>A p.G1167R | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267606745, CM014044; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS14 | c.1343G>A p.R448H | Missense Mutation (SNP) | VAF 83/226 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); catalogued as rs758220536, COSV64601849; called by muse, mutect2, varscan2
- DNAH7 | c.2062C>T p.R688W | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as rs368478133; called by muse, mutect2, varscan2
- HOOK1 | c.1789G>A p.E597K | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs1027530416, COSV64619028; called by muse, mutect2, varscan2
- INTS13 | c.1768G>A p.D590N | Missense Mutation (SNP) | VAF 12/230 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.174); catalogued as rs1203907436, COSV53901903; called by muse, mutect2
- MROH2B | c.2522C>T p.P841L | Missense Mutation (SNP) | VAF 16/370 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.44); catalogued as rs1288683304; called by muse, mutect2
- NLRP7 | c.766G>C p.D256H | Missense Mutation (SNP) | VAF 18/736 reads (2%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1157709536; called by muse, mutect2
- PADI1 | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 37/312 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.431); catalogued as rs200141204, COSV64937802; called by muse, varscan2
- PARVB | c.715C>T p.R239W | Missense Mutation (SNP) | VAF 30/318 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs775756782; called by muse, mutect2
- SLC44A4 | c.1309C>T p.R437C | Missense Mutation (SNP) | VAF 66/656 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs368732004; called by muse, mutect2, varscan2
- TEX14 | c.3785G>A p.R1262Q (on ENST00000240361 / NM_001201457.2; = p.R1216Q on NM_031272.5) | Missense Mutation (SNP) | VAF 24/252 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs187298992, COSV53628197; called by muse, mutect2
- VWA3B | c.1049C>T p.T350M | Missense Mutation (SNP) | VAF 64/354 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); catalogued as rs374632376; ClinVar: likely benign; called by muse, mutect2, varscan2
- B4GALNT4 | c.1579G>A p.V527M | Missense Mutation (SNP) | VAF 97/626 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- CCDC168 | c.14782G>A p.G4928R | Missense Mutation (SNP) | VAF 68/245 reads (28%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- ETV6 | c.139_140delinsCGCCAGGGCCTCT p.S47Rfs*5 | Frame Shift Ins (INS) | VAF 44/373 reads (12%) | called by pindel, varscan2*
- GRM7 | c.1907T>G p.I636S | Missense Mutation (SNP) | VAF 98/230 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- GRTP1 | c.52G>C p.E18Q | Missense Mutation (SNP) | VAF 24/365 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.062); called by muse, mutect2
- IGSF9 | c.3065C>G p.T1022S (on ENST00000368094 / NM_001135050.2; = p.T1006S on NM_020789.4) | Missense Mutation (SNP) | VAF 20/554 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2
- IKBIP | c.790G>C p.E264Q | Missense Mutation (SNP) | VAF 18/334 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- NUAK2 | c.1477G>C p.G493R | Missense Mutation (SNP) | VAF 78/450 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- RASSF9 | c.451A>T p.T151S | Missense Mutation (SNP) | VAF 116/293 reads (40%) | SIFT tolerated (0.54); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- SEMA3C | c.2212A>C p.S738R | Missense Mutation (SNP) | VAF 18/296 reads (6%) | SIFT tolerated (0.61); PolyPhen benign (0.001); called by muse, mutect2
- SLCO5A1 | c.1774A>T p.S592C | Missense Mutation (SNP) | VAF 35/181 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- WDFY4 | c.1181A>C p.H394P | Missense Mutation (SNP) | VAF 51/288 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- AVPR1A | c.240G>A p.P80= | Silent (SNP) | VAF 64/449 reads (14%) | catalogued as COSV54546060; called by muse, mutect2, varscan2
- BICRA | c.3885G>T p.P1295= | Silent (SNP) | VAF 77/530 reads (15%) | catalogued as COSV67603719; called by muse, mutect2, varscan2
- DEFB119 | c.126C>T p.N42= | Silent (SNP) | VAF 41/342 reads (12%) | catalogued as rs112690953; called by muse, varscan2
- SMU1 | c.519G>A p.Q173= | Silent (SNP) | VAF 68/139 reads (49%) | catalogued as rs757129552; called by muse, mutect2, varscan2
- SOWAHA | c.1521C>T p.S507= | Silent (SNP) | VAF 14/364 reads (4%) | catalogued as rs1261670257; called by muse, mutect2
- UNC80 | c.2454G>C p.L818= | Silent (SNP) | VAF 40/265 reads (15%) | called by muse, mutect2, varscan2
- ZNF33A | c.1842A>C p.G614= (on ENST00000458705 / NM_006974.3; = p.G615= on NM_006954.2) | Silent (SNP) | VAF 7/187 reads (4%) | called by muse, mutect2
- ARHGAP42 | c.*3717G>A | 3'UTR (SNP) | VAF 22/308 reads (7%) | catalogued as COSV53982054; called by muse, mutect2
- IGLV6-57 | chr22:22196276 ins AAC | 3'Flank (INS) | VAF 19/88 reads (22%) | called by mutect2, pindel, varscan2
- MASP1 | c.1303+5686C>T | Intron (SNP) | VAF 68/415 reads (16%) | catalogued as rs745444812, COSV56221819, COSV99962704; called by muse, mutect2, varscan2
